Somatic mutation profile of tumor specimen TARGET-20-PAEFGT-04A (aliquot TARGET-20-PAEFGT-04A-01D) from TARGET case TARGET-20-PAEFGT, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.9 years (5,452 days).
Specimen TARGET-20-PAEFGT-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59310093-d341-479c-a1f7-97fbb7b80df7.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PAEFGT-14A (Bone Marrow Normal), aliquot TARGET-20-PAEFGT-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc2db776-f2f2-4b1d-9ad3-16cb48cfcd90

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 1, Missense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYC | c.179C>A p.P60H (on ENST00000377970; = p.P75H on NM_002467.6) | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52367558, COSV52380145; called by muse, mutect2, varscan2
- NPM1 | c.863_864insCATG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 10/36 reads (28%) | catalogued as rs1554138188, COSV51544217, COSV51551832, COSV51558469, COSV51558827, COSV51561854; called by mutect2, pindel, varscan2
- WT1 | c.1107_1111del p.A370* | Frame Shift Del (DEL) | VAF 44/74 reads (59%) | called by pindel, varscan2
